Somatic mutation profile of tumor specimen C3L-02175-01 (aliquot CPT0100410009) from CPTAC case C3L-02175, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 48.9 years (17,859 days).
Specimen C3L-02175-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7481e8c4-4d29-4a00-a744-c02ff7bbf0b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02175-31 (Blood Derived Normal), aliquot CPT0101930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc7f26d0-3847-42c7-b7dd-5caef31cbef4

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Intron 5, 3'Flank 2, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRG3 | c.553T>C p.C185R | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775123723; called by muse, mutect2, varscan2
- PLXNA2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398435180, COSV65443283; called by muse, mutect2
- VHL | c.374dup p.H125Qfs*7 | Frame Shift Ins (INS) | VAF 76/447 reads (17%) | catalogued as CI071465, COSV56548898; called by mutect2, pindel, varscan2
- VIL1 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1173843923; called by muse, mutect2, varscan2
- ACAD8 | c.1160A>C p.Y387S | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BCCIP | c.906A>C p.Q302H | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2
- CARD10 | c.1337T>G p.L446R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- DNAH10 | c.10288T>G p.F3430V (on ENST00000409039; = p.F3369V on NM_207437.3) | Missense Mutation (SNP) | VAF 21/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- EP400 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- FANCB | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO32 | c.338_362del p.I113Tfs*8 | Frame Shift Del (DEL) | VAF 26/264 reads (10%) | called by mutect2, pindel
- FLNA | c.990A>C p.A330= | Splice Region (SNP) | VAF 65/605 reads (11%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.1588A>C p.K530Q (on ENST00000253928 / NM_001308068.2; = p.K529Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HDLBP | c.1080+1del p.X360_splice | Splice Site (DEL) | VAF 21/220 reads (10%) | called by mutect2, pindel
- LRPPRC | c.3825+2T>C p.X1275_splice | Splice Site (SNP) | VAF 14/379 reads (4%) | called by muse, mutect2
- OR5M11 | c.818T>A p.I273K | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2
- PRRG1 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2
- RRAGA | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SLC7A3 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- TIAM1 | c.4429G>T p.G1477C | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ZNF292 | c.250A>C p.S84R | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF398 | c.996T>A p.Y332* (on ENST00000475153 / NM_170686.3; = p.Y161* on NM_020781.4) | Nonsense Mutation (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- CPA6 | c.732T>C p.H244= | Silent (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- CPNE7 | c.351G>T p.L117= | Silent (SNP) | VAF 8/147 reads (5%) | called by muse, mutect2
- SP7 | c.1182C>A p.G394= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as rs1292803480; called by muse, mutect2
- TANGO6 | c.1713G>A p.E571= | Silent (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- UNK | c.2107C>A p.R703= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV52885346; called by muse, mutect2
- WDR7 | c.2479C>T p.L827= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as rs758300016; called by muse, mutect2, varscan2
- ACSM2B | c.597-162dup | Intron (INS) | VAF 36/317 reads (11%) | called by mutect2, varscan2
- FAS | c.*1438A>T | 3'UTR (SNP) | VAF 20/166 reads (12%) | catalogued as rs1275779748; called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1263C>T | Intron (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- KCNAB2 | c.502+796T>C | Intron (SNP) | VAF 32/320 reads (10%) | catalogued as rs756615015; called by muse, mutect2
- RAD50 | c.1793+772T>G | Intron (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- SAA2 | chr11:18240285 T>A | 3'Flank (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- TEX35 | chr1:178525446 T>A | 3'Flank (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- VAV1 | c.204+11191T>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
